Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4NY, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4NY-01A (Primary Tumor).

FINAL DIAGNOSIS:

Summary Statement

The right pneumonectomy and lymph node dissection shows a diffuse malignant mesothelioma, mixed epithelioid and sarcomatous type, with invasion of the parietal pleura, lung, diaphragmatic muscle, and azygous vein, but with no evidence of lymph node metastases. Pathologic stage: T3 N0 MX.

PART 1: SOFT TISSUE, "CHEST WALL ON TOP OF 5TH RIB, RIGHT", BIOPSY -
SUTURE GRANULOMA. NO EVIDENCE OF MALIGNANCY.

PART 2: BONE, "PARTIAL 7TH RIB, RIGHT", RESECTION -
SPECIMEN UNDERGOING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.

PART 3: PLEURA, BIOPSY -
A. DIFFUSE MALIGNANT MESOTHELIOMA.
B. SUTURE GRANULOMA.

PART 4: BONE, "PARTIAL RIGHT 5TH RIB", RESECTION -
SPECIMEN UNDERGOING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.

PART 5: SOFT TISSUE, CHEST WALL, BIOPSY -
ACUTE FIBRINOUS AND ORGANIZING PLEURITIS ASSOCIATED WITH FOREIGN BODY GIANT CELL REACTION.
NO EVIDENCE OF MALIGNANT MESOTHELIOMA.

PART 6: LYMPH NODE, LEVEL 10 LYMPH NODE, BIOPSY -
FIVE (5) FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF MALIGNANT MESOTHELIOMA.

PART 7: SOFT TISSUE, "VAGUS", BIOPSY -
A. LARGE NERVE WITH NO SIGNIFICANT ABNORMALITY.
B. THREE (3) FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC MALIGNANCY.

PART 8: LYMPH NODE, SUBCARINAL LYMPH NODE, BIOPSY -
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 9: BRONCHUS, "FREE END MARKS PROXIMAL MARGIN", RESECTION -
PORTIONS OF BRONCHUS AND BRONCHIAL MUCOSA WITH NO SIGNIFICANT PATHOLOGIC ABNORMALITY.

PART 10: LYMPH NODE, "LYMPH NODE NEAR INFERIOR PULMONARY LIGAMENT", BIOPSY -
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 11: LUNG, RIGHT, PLEUROPLEURONECTOMY -
A. DIFFUSE MALIGNANT MESOTHELIOMA, MIXED EPITHELIOID AND FIBROSARCOMATOUS TYPE, WITH
INVASION OF THE PARIETAL PLEURA, PLEURAL ADIPOSE TISSUE, DIAPHRAGMATIC MUSCLE, FISSURE
AND PULMONARY PARENCHYMA WITH INTRAPARENCHYMAL NODULES. PATHOLOGIC STAGE: T3 N0
MX.
B. APICAL CAP OF LEFT UPPER LOBE.
C. TWENTY-FIVE (25) N1 LYMPH NODES WITH NO EVIDENCE OF METASTATIC MALIGNANT MESOTHELIOMA.

PART 12: PERICARDIUM, PERICARDECTOMY -
DIFFUSE MALIGNANT MESOTHELIOMA.

PART 13: SOFT TISSUE, "NODULE ON AZYGUS VEIN", BIOPSY -
DIFFUSE MALIGNANT MESOTHELIOMA.

1CD-0-3

Mesothelioma, biphasic, NOS 9853/3
Site: pleura, NOS C38.4

lw 10/25/12

COMMENT:

The malignant mesothelioma for the most part shows a tubulopapillary growth pattern associated with abundant myxoid stroma, and extracellular hyaluronic acid production. In occasional areas, a spindle cell component is identified and for this reason we have classified this as a mixed epithelioid and fibrosarcomatous malignant mesothelioma.

Previous material on this case has been worked up for a variety of mesothelial markers
immunophenotype characteristic of malignant mesothelioma.

revealing an

The underlying lung shows no evidence of asbestosis and iron stains fail to reveal significant numbers of ferruginous bodies.

Addendum

Sections of the Part 2 and Part 4 bone samples representing "partial 7th rib right" and "partial right 5th rib" show normal bone and bone marrow with trilineage representation and maturation. No evidence of malignancy is seen.

1CD-0-3

	Yes	No
Criteria		
PPA Discrepancy		
Qual/Spec, Inconsistent Primary Listed		
Review Initials: BFB	Date Reviewed:	

lw 9/25/12

Source: NCI Genomic Data Commons file 37e94f7f-13f1-4fc9-9c60-7b3636180edc (TCGA-LK-A4NY.841AD538-D6BE-4560-BA50-D33557B130CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).